Somatic mutation profile of tumor specimen MP2PRT-PAULAU-TMP1-A (aliquot MP2PRT-PAULAU-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAULAU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,794 days).
Specimen MP2PRT-PAULAU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7933730-a716-442b-8a85-fb2db985175a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAULAU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAULAU-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a357fc8-bd06-4e54-8a3b-8adfae32123f

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.4729G>A p.V1577I | Missense Mutation (SNP) | VAF 106/236 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.611); catalogued as rs1301774090, COSV56860641; called by muse, mutect2, varscan2
- ADD1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 238/389 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370911124; called by muse, mutect2, varscan2
- ASXL1 | c.1549C>T p.Q517* | Nonsense Mutation (SNP) | VAF 194/475 reads (41%) | catalogued as rs755464186; called by muse, mutect2, varscan2
- DNAH17 | c.8381G>A p.R2794Q | Missense Mutation (SNP) | VAF 183/603 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as rs187009220; called by muse, mutect2, varscan2
- OR4C15 | c.57del p.L19Ffs*2 | Frame Shift Del (DEL) | VAF 102/277 reads (37%) | catalogued as COSV58955337; called by mutect2, pindel, varscan2
- SPATA31A1 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 52/419 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs1181569449; called by muse, mutect2
- BTBD7 | c.3298G>C p.G1100R | Missense Mutation (SNP) | VAF 184/619 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- CACNA1F | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 170/723 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DGKI | c.715G>T p.G239* | Nonsense Mutation (SNP) | VAF 78/220 reads (35%) | called by muse, mutect2, varscan2
- FRAS1 | c.4647C>G p.H1549Q | Missense Mutation (SNP) | VAF 276/441 reads (63%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- NMU | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 174/287 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- PKHD1L1 | c.11470C>G p.L3824V | Missense Mutation (SNP) | VAF 170/362 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- SP4 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 167/364 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- TMEM132B | c.2612G>A p.S871N | Missense Mutation (SNP) | VAF 192/392 reads (49%) | SIFT tolerated (0.66); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- UNC93A | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 112/347 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNGB1 | c.1881C>T p.C627= | Silent (SNP) | VAF 150/335 reads (45%) | catalogued as rs369525244, COSV51900241; called by muse, mutect2, varscan2
- MGAT3 | c.654C>T p.F218= | Silent (SNP) | VAF 15/504 reads (3%) | catalogued as rs867840954, COSV100362029, COSV57867867; called by muse, mutect2
- PCDHA4 | c.132C>T p.F44= | Silent (SNP) | VAF 150/342 reads (44%) | catalogued as COSV63540098; called by muse, mutect2, varscan2
- PPP1R17 | c.258T>C p.I86= | Silent (SNP) | VAF 130/253 reads (51%) | catalogued as rs779961240; called by muse, mutect2, varscan2
